Somatic mutation profile of tumor specimen MP2PRT-PATITF-TMP1-A (aliquot MP2PRT-PATITF-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATITF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,559 days).
Specimen MP2PRT-PATITF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbed8eb0-1122-44d9-acd6-35041dfdfa5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATITF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATITF-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b94bd670-7408-4838-a9ae-c497ff1ed95a

The open-access MAF lists 25 somatic variants for this specimen: 15 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 15, Silent 10.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.3969C>G p.F1323L | Missense Mutation (SNP) | VAF 46/422 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100622738; called by muse, mutect2, varscan2
- CDH22 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 50/511 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1399372771; called by muse, mutect2
- EXOC3L4 | c.228C>A p.F76L | Missense Mutation (SNP) | VAF 62/569 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101197559, COSV101197630; called by muse, mutect2, varscan2
- EZH2 | c.1687A>G p.K563E (on ENST00000460911 / NM_001203247.2; = p.K568E on NM_004456.5) | Missense Mutation (SNP) | VAF 63/356 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM1312131, COSV57447582; called by muse, mutect2, varscan2
- H3C3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 73/448 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV63550652, COSV63551431, COSV63551470; called by muse, mutect2, varscan2
- MRPL35 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 69/456 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs369534784; called by muse, mutect2, varscan2
- MYO7B | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 112/451 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs1346584676; called by muse, mutect2, varscan2
- NMBR | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 13/410 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1419605812, COSV57802298; called by muse, mutect2
- NUDT12 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as rs774821755, COSV50090511, COSV50090702; called by muse, mutect2, varscan2
- ARNTL2 | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CBLN2 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 94/690 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CORO6 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA8 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); called by muse, mutect2
- SLC6A13 | c.716C>A p.T239K | Missense Mutation (SNP) | VAF 95/381 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SYTL4 | c.683A>G p.K228R | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDCP2 | c.1500G>A p.A500= | Silent (SNP) | VAF 83/610 reads (14%) | catalogued as rs1463473164; called by muse, mutect2, varscan2
- GAP43 | c.81A>T p.P27= | Silent (SNP) | VAF 28/356 reads (8%) | called by muse, mutect2
- HABP2 | c.393T>A p.P131= | Silent (SNP) | VAF 69/477 reads (14%) | called by muse, mutect2, varscan2
- HTR3A | c.912C>T p.L304= | Silent (SNP) | VAF 77/507 reads (15%) | called by muse, mutect2, varscan2
- IL21 | c.45G>A p.L15= | Silent (SNP) | VAF 51/365 reads (14%) | called by muse, mutect2, varscan2
- ITGA2B | c.1020C>T p.G340= | Silent (SNP) | VAF 125/402 reads (31%) | catalogued as rs1423193492; called by muse, mutect2, varscan2
- ITGBL1 | c.87G>A p.S29= | Silent (SNP) | VAF 48/357 reads (13%) | catalogued as COSV66022007; called by muse, mutect2, varscan2
- NUTM2D | c.816G>C p.R272= | Silent (SNP) | VAF 37/289 reads (13%) | catalogued as rs778829842; called by muse, mutect2, varscan2
- SP140 | c.2151C>T p.H717= | Silent (SNP) | VAF 99/367 reads (27%) | called by muse, mutect2, varscan2
- ZNF200 | c.66G>A p.P22= | Silent (SNP) | VAF 56/387 reads (14%) | catalogued as rs373072784; called by muse, mutect2, varscan2
